Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A2G6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A2G6-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

1cD-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1
JW
6/3/11

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10 A11 J1 B1 B2 B3
B4 C1 C2 C3
C4 C5 D1 E1 E2 F1 F2 G1 H1 I1 I2
Uterus with right ovary (2.3 x 1.2 x 0.9 cm), 3.0 cm of
right
fallopian tube, left ovary (2.7 x 1.3 x 0.8 cm), and 5.0
cm of left
fallopian tube (together weighing 145.0 grams), right and
left
para-aortic lymph nodes, right and left pelvic lymph
nodes, right
and left gonadal vessels, additional left para-aortic
lymph node
above inferior mesenteric artery (1.6 x 0.8 x 0.6 cm),
sigmoid
mesentery biopsy (2.3 x 0.5 x 0.3 cm), proximal ileal
mesentery
biopsy (1.1 x 0.9 0.7 cm), and distal ileal mesentery
biopsy (1.0 x
0.8 x 0.6 cm).

DIAGNOSIS:

Uterus, hysterectomy: Endometrial adenocarcinoma,
endometrioid type
with squamous differentiation, FIGO grade III (of
III) forming a 6.3
x 4.5 x 4.2 cm uterine mass. The tumor invades through
the
myometrium to a depth of 1.5 cm (myometrial thickness 1.6
cm). The
lower uterine segment and cervix is also involved by
tumor.
Immunohistochemical stains (estrogen receptor,
progesterone
receptor, pCEA, vimentin) and HPV in situ hybridization
was
performed on the paraffin embedded uterine tissue. The
neoplastic
cells are focally positive for estrogen receptor, positive
for
vimentin and lack staining for progesterone receptor and
pCEA. HPV
in situ hybridization is negative. The morphology and

[page 2 of 2]
immunohistochemical findings support an endometrial primary.

Ovaries and fallopian tubes, right and left, salpingo-oophorectomy:

Ovaries and fallopian tubes without diagnostic abnormalities, bilaterally.

Lymph nodes, right and left pelvic, excision: A single (of 7) right obturator and a single (of 4) left external iliac pelvic lymph nodes are involved by metastatic carcinoma. Multiple right (5 external iliac, 2 internal iliac, 3 common iliac) and left (4 obturator, 5 common iliac) pelvic lymph nodes are negative for tumor.

Lymph nodes, right and left para-aortic, excision: Multiple right (5 above inferior mesenteric artery; 4 below inferior mesenteric artery) and left (4 above inferior mesenteric artery; 6 below inferior mesenteric artery) lymph nodes are negative for tumor. A single additional separately submitted left para-aortic lymph node above inferior mesenteric artery is also negative for tumor.

Gonadal vessels, right and left, excision: Negative for tumor, bilaterally.

Sigmoid mesentery, biopsy: Negative for tumor.

Ileal mesentery, proximal and distal, biopsy: Negative for tumor, both sites.

Source: NCI Genomic Data Commons file 58142cb3-42d6-4b36-961f-b0137f014cde (TCGA-D1-A2G6.3375E2AF-173B-4263-84A8-8535DF33BA69.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).